Somatic mutation profile of tumor specimen TCGA-BR-6454-01A (aliquot TCGA-BR-6454-01A-11D-1800-08) from TCGA case TCGA-BR-6454, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G3; Age at diagnosis: 58.9 years (21,501 days).
Specimen TCGA-BR-6454-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9272517a-5964-4e68-a8b5-5dfc77efa37e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BR-6454-11A (Solid Tissue Normal), aliquot TCGA-BR-6454-11A-01D-1800-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c7fdb234-8275-48da-9241-5a7a33801610

The open-access MAF lists 154 somatic variants for this specimen: 113 protein-altering or splice-affecting, 39 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 94, Silent 39, Nonsense Mutation 11, Frame Shift Del 3, Splice Site 2, Frame Shift Ins 2, 5'Flank 1, 5'UTR 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C5orf49 | c.389A>C p.K130T | Missense Mutation (SNP) | VAF 41/154 reads (27%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.876); catalogued as rs200323831; called by muse, mutect2, varscan2
- MAGI2 | c.1808T>G p.L603R | Missense Mutation (SNP) | VAF 7/55 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV62636665, COSV62664406; called by muse, mutect2, varscan2
- PIK3CA | c.3062A>G p.Y1021C | Missense Mutation (SNP) | VAF 15/71 reads (21%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs121913288, CM126695, COSV55882161, COSV55997924; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADAMTSL3 | c.661G>T p.A221S | Missense Mutation (SNP) | VAF 16/133 reads (12%) | SIFT tolerated (0.42); PolyPhen benign (0.062); catalogued as COSV54461273; called by muse, mutect2, varscan2
- ADAT2 | c.542C>T p.S181L | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.047); catalogued as rs757563168, COSV99395568; called by muse, mutect2, varscan2
- ADNP | c.2128C>G p.P710A | Missense Mutation (SNP) | VAF 12/250 reads (5%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV62426457; called by muse, mutect2
- ADRA1A | c.412G>A p.V138I | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.812); catalogued as COSV52370947; called by muse, mutect2, varscan2
- AKAP9 | c.3294A>C p.E1098D | Missense Mutation (SNP) | VAF 31/358 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV62354272; called by muse, mutect2
- ANXA4 | c.248T>A p.V83E | Missense Mutation (SNP) | VAF 20/121 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.511); catalogued as COSV67849320; called by muse, mutect2, varscan2
- AR | c.710A>G p.K237R | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT tolerated, low confidence (0.21); PolyPhen probably damaging (0.997); catalogued as COSV65961700; called by muse, mutect2, varscan2
- ARAP3 | c.4390G>T p.E1464* | Nonsense Mutation (SNP) | VAF 21/97 reads (22%) | catalogued as COSV53353297, COSV99500242; called by muse, mutect2, varscan2
- ATM | c.1320_1321del p.Q441Afs*45 | Frame Shift Del (DEL) | VAF 34/130 reads (26%) | catalogued as rs1555070745; called by pindel, varscan2
- ATM | c.4498C>T p.Q1500* | Nonsense Mutation (SNP) | VAF 100/249 reads (40%) | catalogued as COSV53763817; called by muse, mutect2, varscan2
- BAIAP2L2 | c.1433G>C p.S478T | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.787); catalogued as COSV57636802; called by muse, mutect2, varscan2
- BLM | c.1478A>G p.N493S | Missense Mutation (SNP) | VAF 16/234 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61926298; called by muse, mutect2
- CDH7 | c.990T>G p.D330E | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as COSV59891432; called by muse, mutect2, varscan2
- CEMIP | c.1129T>C p.Y377H | Missense Mutation (SNP) | VAF 16/152 reads (11%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.018); catalogued as rs779741917, COSV54997906; called by muse, mutect2
- CLSTN2 | c.265G>T p.E89* | Nonsense Mutation (SNP) | VAF 33/233 reads (14%) | catalogued as COSV71723717; called by muse, mutect2, varscan2
- CYP2A7 | c.1085T>A p.F362Y | Missense Mutation (SNP) | VAF 38/243 reads (16%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.971); catalogued as rs150178247, COSV52504531; called by muse, mutect2, varscan2
- DGKH | c.995C>T p.P332L | Missense Mutation (SNP) | VAF 18/141 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54938090; called by muse, mutect2, varscan2
- DNAH5 | c.532G>A p.A178T | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs781356156, COSV54243463; called by muse, mutect2, varscan2
- DYRK1A | c.183G>C p.Q61H | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.626); catalogued as COSV58295473; called by muse, mutect2, varscan2
- DZANK1 | c.594G>C p.E198D | Missense Mutation (SNP) | VAF 18/145 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.634); catalogued as COSV52755367, COSV99361634; called by muse, mutect2, varscan2
- EDC3 | c.710C>G p.P237R | Missense Mutation (SNP) | VAF 42/177 reads (24%) | SIFT tolerated (0.37); PolyPhen benign (0.188); catalogued as COSV59341260; called by muse, mutect2, varscan2
- EPB41L1 | c.1198C>T p.Q400* | Nonsense Mutation (SNP) | VAF 8/109 reads (7%) | catalogued as COSV52442172, COSV99148717; called by muse, mutect2
- EPB41L4B | c.2407A>T p.K803* | Nonsense Mutation (SNP) | VAF 9/57 reads (16%) | catalogued as COSV65804538; called by muse, mutect2, varscan2
- ERBB3 | c.1999C>A p.R667S | Missense Mutation (SNP) | VAF 68/163 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57247893, COSV57261351; called by muse, mutect2, varscan2
- EVI2A | c.583A>C p.T195P | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55986688; called by muse, mutect2, varscan2
- F13B | c.1113T>A p.H371Q | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV66375182; called by muse, mutect2, varscan2
- F8 | c.1940C>A p.S647* | Nonsense Mutation (SNP) | VAF 15/34 reads (44%) | catalogued as COSV100811914, COSV64277169; called by muse, mutect2, varscan2
- FAM83F | c.1036C>T p.R346W | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.021); catalogued as rs145428025; called by muse, mutect2, varscan2
- FAT3 | c.7945G>A p.D2649N | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs1162671325, COSV53088584; called by muse, mutect2, varscan2
- FAT4 | c.8446G>T p.A2816S | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT tolerated (0.75); PolyPhen benign (0.029); catalogued as COSV58701213; called by muse, mutect2, varscan2
- GLT8D2 | c.350T>C p.V117A | Missense Mutation (SNP) | VAF 23/126 reads (18%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.994); catalogued as rs1050116852, COSV62562738; called by muse, mutect2, varscan2
- GPN1 | c.532T>A p.Y178N | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53116703; called by muse, mutect2, varscan2
- GPR153 | c.826C>T p.P276S | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0.277); catalogued as COSV64938836; called by muse, mutect2, varscan2
- GPR50 | c.997C>T p.R333C | Missense Mutation (SNP) | VAF 39/121 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs200075966, COSV54438571, COSV54441705; called by muse, mutect2, varscan2
- H1-2 | c.518G>C p.S173T | Missense Mutation (SNP) | VAF 115/245 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs145521943, COSV59191905; called by muse, mutect2, varscan2
- H4C5 | c.113T>A p.L38H | Missense Mutation (SNP) | VAF 44/117 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV63487200; called by muse, mutect2, varscan2
- HECTD1 | c.5537A>G p.Y1846C | Missense Mutation (SNP) | VAF 35/95 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs536602982, COSV67946830; called by muse, mutect2, varscan2
- IGHMBP2 | c.2029A>G p.S677G | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT tolerated (0.48); PolyPhen benign (0.026); catalogued as COSV54824949; called by muse, mutect2
- IL20 | c.325A>T p.I109F | Missense Mutation (SNP) | VAF 71/472 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); catalogued as rs1397492907, COSV65584973; called by muse, mutect2, varscan2
- ILDR2 | c.308T>C p.V103A | Missense Mutation (SNP) | VAF 19/149 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54834141; called by muse, mutect2, varscan2
- KCNA3 | c.1597G>A p.E533K | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.154); catalogued as COSV63902245; called by muse, mutect2, varscan2
- KDM3A | c.3508C>G p.P1170A | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57224503; called by muse, mutect2, varscan2
- KIF16B | c.766A>C p.S256R | Missense Mutation (SNP) | VAF 32/196 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61711480; called by muse, mutect2, varscan2
- KIF2B | c.1256A>C p.N419T | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52133939; called by muse, mutect2, varscan2
- KLHL25 | c.1183G>T p.G395* | Nonsense Mutation (SNP) | VAF 17/83 reads (20%) | catalogued as COSV61996019; called by muse, mutect2, varscan2
- KRTAP19-7 | c.94T>G p.F32V | Missense Mutation (SNP) | VAF 18/166 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as COSV58366427; called by muse, mutect2, varscan2
- LILRA2 | c.1205A>G p.N402S | Missense Mutation (SNP) | VAF 24/110 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as COSV52195293; called by muse, varscan2
- LINGO4 | c.751G>A p.G251R | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63214349, COSV63215811; called by muse, mutect2, varscan2
- MAF | c.125T>A p.I42N | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV58155037; called by muse, mutect2, varscan2
- MARCHF11 | c.991G>A p.E331K | Missense Mutation (SNP) | VAF 40/93 reads (43%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.883); catalogued as rs199643997; called by muse, mutect2, varscan2
- MDM4 | c.562C>T p.L188F | Missense Mutation (SNP) | VAF 16/113 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.086); catalogued as COSV65796455; called by muse, mutect2, varscan2
- MME | c.844G>A p.E282K | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.425); catalogued as COSV100852487, COSV64709353, COSV64709653; called by muse, mutect2, varscan2
- MNS1 | c.281C>T p.A94V | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.921); catalogued as COSV53069750; called by muse, mutect2, varscan2
- MST1R | c.3705C>G p.D1235E | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.681); catalogued as COSV56572161; called by muse, mutect2, varscan2
- MUC16 | c.15719A>C p.K5240T | Missense Mutation (SNP) | VAF 25/153 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.023); catalogued as COSV67482693; called by muse, mutect2, varscan2
- MX1 | c.1430C>T p.T477M | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.329); catalogued as rs199860719; called by muse, mutect2, varscan2
- MXRA5 | c.8354G>T p.G2785V | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54245037; called by muse, mutect2, varscan2
- MYH3 | c.2084G>A p.R695Q | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.047); catalogued as rs943488185, COSV56867669; called by muse, mutect2, varscan2
- MYH9 | c.5195C>T p.A1732V | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.196); catalogued as COSV53391190; called by muse, mutect2
- NCOA7 | c.2559C>G p.F853L | Missense Mutation (SNP) | VAF 8/135 reads (6%) | SIFT tolerated (0.26); PolyPhen benign (0.137); catalogued as COSV57658392; called by muse, mutect2
- NELL2 | c.1748G>T p.C583F | Missense Mutation (SNP) | VAF 51/128 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61582297; called by muse, mutect2, varscan2
- NLE1 | c.716A>T p.E239V | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT tolerated (0.78); PolyPhen benign (0.224); catalogued as COSV62604899; called by muse, mutect2
- NMUR1 | c.874C>T p.R292W | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs760642418, COSV59403892; called by muse, mutect2, varscan2
- NRXN1 | c.2536A>T p.N846Y | Missense Mutation (SNP) | VAF 25/98 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58479031; called by muse, mutect2, varscan2
- NUP210L | c.2769A>C p.E923D | Missense Mutation (SNP) | VAF 14/150 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.675); catalogued as COSV55154320; called by muse, mutect2
- OR10X1 | c.236T>G p.L79R | Missense Mutation (SNP) | VAF 17/110 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1344826882, COSV63767786; called by muse, mutect2, varscan2
- OR5T3 | c.204C>A p.H68Q | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.962); catalogued as COSV57381185; called by muse, mutect2, varscan2
- PARD3B | c.1270G>T p.D424Y | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100593320, COSV62523560; called by muse, mutect2, varscan2
- PGPEP1L | c.487T>G p.L163V | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as COSV51341777; called by muse, mutect2, varscan2
- PHF20 | c.2482C>T p.R828C | Missense Mutation (SNP) | VAF 18/103 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs745681312, COSV64977057; called by muse, mutect2, varscan2
- PNLIPRP3 | c.463T>A p.F155I | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.246); catalogued as COSV65047494, COSV65049387; called by muse, mutect2, varscan2
- PSME3 | c.190C>A p.L64I | Missense Mutation (SNP) | VAF 70/151 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.081); catalogued as COSV53200094; called by muse, mutect2, varscan2
- PTPRD | c.5461A>G p.I1821V | Missense Mutation (SNP) | VAF 32/109 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.791); catalogued as COSV61938252, COSV61971876; called by muse, mutect2, varscan2
- RAPGEF1 | c.1752G>T p.K584N | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.786); catalogued as COSV64699676; called by muse, mutect2, varscan2
- RBM4 | c.457G>A p.A153T | Missense Mutation (SNP) | VAF 27/141 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.052); catalogued as COSV59519870; called by muse, mutect2, varscan2
- RGS22 | c.1267A>G p.K423E | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.784); catalogued as COSV62665618; called by mutect2, varscan2
- RSPO3 | c.365T>A p.L122H | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as COSV63152328; called by muse, mutect2, varscan2
- SLC12A5 | c.1712G>A p.G571D (on ENST00000454036 / NM_001134771.2; = p.G548D on NM_020708.5) | Missense Mutation (SNP) | VAF 41/414 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54799132, COSV54802493; called by muse, mutect2
- SLC22A1 | c.1218G>A p.M406I | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as rs1334195659, COSV61453470; called by muse, mutect2, varscan2
- SLC46A3 | c.118A>T p.T40S | Missense Mutation (SNP) | VAF 15/123 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as COSV57183511; called by muse, mutect2, varscan2
- SLC6A16 | c.122C>A p.S41Y | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.35); catalogued as rs954706679, COSV60029399; called by muse, varscan2
- SOX5 | c.1102G>T p.A368S | Missense Mutation (SNP) | VAF 18/129 reads (14%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as rs1452258093, COSV58641983; called by muse, mutect2, varscan2
- SPTB | c.3626A>T p.K1209M | Missense Mutation (SNP) | VAF 59/241 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.729); catalogued as rs752722915, COSV67634026; called by muse, mutect2, varscan2
- SSH2 | c.416G>A p.G139D | Missense Mutation (SNP) | VAF 13/141 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV52178145; called by muse, mutect2
- SSU72P8 | c.496G>A p.D166N | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.393); catalogued as rs782614965, COSV66361339; called by muse, mutect2, varscan2
- ST8SIA5 | c.966G>A p.W322* | Nonsense Mutation (SNP) | VAF 29/112 reads (26%) | catalogued as COSV59334048; called by muse, mutect2, varscan2
- STKLD1 | c.326A>C p.E109A | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.465); catalogued as COSV64314080; called by muse, mutect2, varscan2
- TCHH | c.4921C>T p.R1641C | Missense Mutation (SNP) | VAF 23/164 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.454); catalogued as COSV64276853; called by muse, mutect2, varscan2
- TEAD2 | c.290G>A p.R97Q | Missense Mutation (SNP) | VAF 82/200 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs1310097180, COSV55561767; called by muse, mutect2, varscan2
- TENM3 | c.5914G>T p.E1972* | Nonsense Mutation (SNP) | VAF 42/222 reads (19%) | catalogued as COSV69315412; called by muse, mutect2, varscan2
- TEX15 | c.5045T>G p.L1682* (on ENST00000256246; = p.L2065* on NM_001350162.2) | Nonsense Mutation (SNP) | VAF 21/111 reads (19%) | catalogued as COSV56351350, COSV99821559; called by muse, mutect2, varscan2
- TEX9 | c.869G>C p.S290T | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV61879904; called by muse, mutect2, varscan2
- TG | c.1204G>T p.A402S | Missense Mutation (SNP) | VAF 14/250 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.084); catalogued as COSV55089052; called by muse, mutect2
- TGM1 | c.1604A>T p.N535I | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.026); catalogued as COSV52864684; called by muse, mutect2, varscan2
- TMEM219 | c.469C>A p.P157T | Missense Mutation (SNP) | VAF 22/175 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54244532; called by muse, mutect2, varscan2
- TRRAP | c.1109C>T p.T370I | Missense Mutation (SNP) | VAF 8/133 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.969); catalogued as COSV62851441; called by muse, mutect2
- TRRAP | c.9140T>A p.I3047N (on ENST00000359863 / NM_001244580.1; = p.I3018N on NM_003496.3) | Missense Mutation (SNP) | VAF 33/389 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV62851448; called by muse, mutect2
- TSC2 | c.4370G>A p.R1457Q | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs1060500952, COSV51922339; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- WASHC2A | c.3239G>A p.R1080Q | Missense Mutation (SNP) | VAF 52/127 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1221692294; called by muse, mutect2, varscan2
- ZNF227 | c.2400G>T p.*800Yext*2 | Nonstop Mutation (SNP) | VAF 11/36 reads (31%) | catalogued as COSV57313289; called by mutect2, varscan2
- ZNF793 | c.485A>G p.K162R | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.062); catalogued as COSV71325134; called by muse, mutect2
- ZNF804B | c.1024G>T p.E342* | Nonsense Mutation (SNP) | VAF 7/62 reads (11%) | catalogued as rs778624854, COSV60817282, COSV60844923, COSV99048271; called by muse, mutect2, varscan2
- ACVRL1 | c.18del p.R7Gfs*5 | Frame Shift Del (DEL) | VAF 8/41 reads (20%) | called by mutect2, pindel, varscan2
- KCNN2 | c.1282_1283del p.R428Gfs*46 (on ENST00000264773; = p.R640Gfs*46 on NM_021614.4) | Frame Shift Del (DEL) | VAF 8/70 reads (11%) | called by mutect2, pindel, varscan2
- RAD51C | c.697_705+10del p.X233_splice | Splice Site (DEL) | VAF 13/106 reads (12%) | called by mutect2, pindel, varscan2
- RRN3 | c.253-6_253-2del p.X85_splice | Splice Site (DEL) | VAF 16/156 reads (10%) | called by mutect2, pindel
- SLC37A2 | c.324T>G p.F108L | Missense Mutation (SNP) | VAF 38/222 reads (17%) | SIFT tolerated (0.63); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- SPANXB1 | c.155A>G p.E52G | Missense Mutation (SNP) | VAF 79/683 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); called by muse, varscan2
- SSH2 | c.1458dup p.S487Lfs*7 | Frame Shift Ins (INS) | VAF 81/265 reads (31%) | called by mutect2, pindel, varscan2
- VAV1 | c.1121_1125dup p.D376Sfs*74 | Frame Shift Ins (INS) | VAF 24/191 reads (13%) | called by mutect2, pindel
- ACTRT1 | c.327C>T p.T109= | Silent (SNP) | VAF 90/265 reads (34%) | catalogued as rs201425054, COSV64419822; called by muse, mutect2, varscan2
- ADCY2 | c.156C>G p.L52= | Silent (SNP) | VAF 12/83 reads (14%) | catalogued as COSV57883104; called by muse, mutect2, varscan2
- ADRB1 | c.798C>T p.L266= | Silent (SNP) | VAF 7/12 reads (58%) | catalogued as COSV65168218; called by muse, mutect2, varscan2
- ARID2 | c.2649C>G p.V883= | Silent (SNP) | VAF 10/108 reads (9%) | catalogued as COSV57611312; called by muse, mutect2
- CNOT3 | c.1695G>C p.L565= | Silent (SNP) | VAF 12/97 reads (12%) | catalogued as COSV55363282, COSV55366654; called by muse, mutect2, varscan2
- CYP2C9 | c.601T>C p.L201= | Silent (SNP) | VAF 51/130 reads (39%) | catalogued as rs1429669733, COSV53251337; called by muse, mutect2, varscan2
- ERVFRD-1 | c.9G>A p.L3= | Silent (SNP) | VAF 9/49 reads (18%) | catalogued as COSV65369716; called by muse, mutect2, varscan2
- FAM209A | c.177A>G p.K59= | Silent (SNP) | VAF 18/228 reads (8%) | catalogued as rs1204847273, COSV54768384; called by muse, mutect2
- FLT1 | c.1182C>T p.D394= | Silent (SNP) | VAF 22/96 reads (23%) | catalogued as rs775108754, COSV56735778; called by muse, mutect2, varscan2
- GDAP1 | c.48G>A p.A16= | Silent (SNP) | VAF 8/39 reads (21%) | catalogued as COSV55186712; called by muse, mutect2, varscan2
- HECW2 | c.2091G>A p.S697= | Silent (SNP) | VAF 5/52 reads (10%) | catalogued as rs754361809, COSV53653353; called by mutect2, varscan2
- HRNR | c.8493T>C p.F2831= | Silent (SNP) | VAF 40/121 reads (33%) | catalogued as COSV64261136; called by muse, mutect2, varscan2
- HRNR | c.594G>C p.G198= | Silent (SNP) | VAF 13/114 reads (11%) | catalogued as COSV64261139; called by muse, mutect2, varscan2
- IFT52 | c.894G>A p.L298= | Silent (SNP) | VAF 51/713 reads (7%) | catalogued as COSV65975737; called by muse, mutect2
- ITGB5 | c.1662C>T p.S554= | Silent (SNP) | VAF 19/167 reads (11%) | catalogued as COSV56151809; called by muse, mutect2, varscan2
- KIAA1549L | c.3336G>A p.V1112= (on ENST00000321505; = p.V1409= on NM_012194.3) | Silent (SNP) | VAF 10/31 reads (32%) | catalogued as COSV55778819; called by muse, mutect2, varscan2
- KRTAP13-2 | c.156C>T p.L52= | Silent (SNP) | VAF 10/109 reads (9%) | catalogued as COSV67761880; called by muse, mutect2
- LYSMD4 | c.129T>C p.S43= (on ENST00000409796 / NM_001284417.2; = p.L14P on NM_152449.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/86 reads (9%) | catalogued as rs751276926, COSV60387345; called by muse, mutect2
- MARCO | c.1437G>A p.G479= | Silent (SNP) | VAF 17/93 reads (18%) | catalogued as COSV59056991; called by muse, mutect2, varscan2
- NCAPD2 | c.870G>A p.L290= | Silent (SNP) | VAF 22/150 reads (15%) | catalogued as COSV59701572; called by muse, mutect2, varscan2
- NLGN2 | c.924G>A p.T308= | Silent (SNP) | VAF 10/50 reads (20%) | catalogued as rs750589662, COSV100259549; called by muse, mutect2, varscan2
- OTOA | c.507G>A p.Q169= | Silent (SNP) | VAF 33/115 reads (29%) | catalogued as COSV53761173; called by muse, mutect2, varscan2
- P2RY10 | c.879T>A p.L293= | Silent (SNP) | VAF 60/241 reads (25%) | catalogued as COSV50684232; called by muse, mutect2, varscan2
- PAPPA | c.1773G>A p.E591= | Silent (SNP) | VAF 26/151 reads (17%) | catalogued as COSV100074177, COSV60289356; called by muse, mutect2, varscan2
- PDZD2 | c.6168C>T p.R2056= | Silent (SNP) | VAF 28/177 reads (16%) | catalogued as COSV56868100; called by muse, mutect2, varscan2
- PHF8 | c.1935C>T p.D645= (on ENST00000357988 / NM_001184896.1; = p.D609= on NM_015107.3) | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as rs782251598, COSV57685983; called by muse, mutect2, varscan2
- POLE | c.3546G>A p.K1182= | Silent (SNP) | VAF 15/82 reads (18%) | catalogued as rs1393231299, COSV57686919; ClinVar: likely benign; called by muse, mutect2, varscan2
- POP5 | c.90C>T p.S30= | Silent (SNP) | VAF 12/75 reads (16%) | catalogued as COSV58047282; called by muse, mutect2, varscan2
- PSG8 | c.1167C>T p.S389= | Silent (SNP) | VAF 126/346 reads (36%) | catalogued as rs753863481, COSV60614315; called by muse, mutect2, varscan2
- PTGER3 | c.1236C>A p.I412= | Silent (SNP) | VAF 28/184 reads (15%) | catalogued as COSV100657268; called by muse, mutect2, varscan2
- RASAL2 | c.1146C>T p.L382= | Silent (SNP) | VAF 16/113 reads (14%) | catalogued as COSV62719670; called by muse, mutect2, varscan2
- RIMS2 | c.228A>G p.G76= | Silent (SNP) | VAF 17/92 reads (18%) | catalogued as COSV68494297; called by muse, mutect2, varscan2
- RIPPLY2 | c.126C>T p.D42= | Silent (SNP) | VAF 7/64 reads (11%) | catalogued as COSV63762909; called by muse, mutect2
- RNF112 | c.1227C>T p.N409= | Silent (SNP) | VAF 34/101 reads (34%) | catalogued as rs377446267; called by muse, mutect2, varscan2
- SLC17A9 | c.147C>G p.V49= | Silent (SNP) | VAF 9/102 reads (9%) | catalogued as COSV64847995; called by muse, mutect2
- SLC25A53 | c.48G>A p.T16= | Silent (SNP) | VAF 16/34 reads (47%) | catalogued as rs781946046, COSV62458806; called by muse, mutect2, varscan2
- SLC6A3 | c.1347G>A p.T449= | Silent (SNP) | VAF 8/90 reads (9%) | catalogued as rs759854756, COSV54367844; called by muse, mutect2
- TMEM132D | c.1809A>G p.Q603= | Silent (SNP) | VAF 10/86 reads (12%) | catalogued as COSV67160830, COSV67161729; called by muse, mutect2, varscan2
- ZNF584 | c.1254C>T p.V418= | Silent (SNP) | VAF 15/90 reads (17%) | catalogued as rs190050516, COSV59723094; called by muse, mutect2, varscan2
- DCAF13 | chr8:103415322 G>A | 5'Flank (SNP) | VAF 13/77 reads (17%) | catalogued as rs747906254, COSV52567449, COSV52568789; called by muse, mutect2, varscan2
- PDE6G | c.-76G>A | 5'UTR (SNP) | VAF 5/25 reads (20%) | catalogued as COSV100458361; called by muse, mutect2, varscan2
